Somatic mutation profile of tumor specimen TCGA-NH-A50V-01A (aliquot TCGA-NH-A50V-01A-11D-A28G-10) from TCGA case TCGA-NH-A50V, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 69.7 years (25,467 days).
Specimen TCGA-NH-A50V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb8af030-e496-4f5e-8949-2aa1b426a581.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NH-A50V-10A (Blood Derived Normal), aliquot TCGA-NH-A50V-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02936c23-c8b7-4cee-b5ac-52b6efdf8079

The open-access MAF lists 177 somatic variants for this specimen: 121 protein-altering or splice-affecting, 42 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 42, Nonsense Mutation 12, 3'UTR 7, 5'UTR 3, Intron 3, Splice Region 2, Frame Shift Ins 2, Frame Shift Del 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 35/125 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 39/116 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.2624C>T p.T875M (on ENST00000303395 / NM_001202435.3; = p.T864M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs121918623, CM000569, CM096132, COSV57669847; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 33/68 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC004593.2 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751272925, COSV99033762; called by muse, mutect2, varscan2
- AGPAT1 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as rs867669239; called by muse, mutect2, varscan2
- AKAP12 | c.1261G>A p.V421I | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1274314918; called by muse, mutect2, varscan2
- APOB | c.2245G>T p.D749Y | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99263186; called by mutect2, varscan2
- ARL13B | c.761C>T p.T254M (on ENST00000394222 / NM_001174150.2; = p.T147M on NM_144996.4) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV57397450; called by muse, mutect2, varscan2
- ATP6V1E2 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as rs150480219, COSV104403651; called by muse, mutect2, varscan2
- BPIFB2 | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV50065392; called by muse, mutect2, varscan2
- CDC16 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as rs771886807, COSV52959686; called by muse, mutect2, varscan2
- CDH16 | c.2296G>A p.V766M | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs140072479; called by mutect2, varscan2
- CDH7 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763799602, COSV59889928; called by muse, mutect2, varscan2
- CHM | c.1184G>A p.G395D | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374389326, CD166181; called by muse, mutect2, varscan2
- CLSTN2 | c.2167C>T p.R723* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | catalogued as rs759220542, COSV71719329; called by muse, mutect2, varscan2
- CNTNAP2 | c.3791T>C p.I1264T | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs376316135; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A1 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs376673751, COSV65431793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD2 | c.3805G>A p.A1269T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53885117, COSV99589716; called by muse, mutect2, varscan2
- DENND5B | c.3624A>C p.L1208F | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.028); catalogued as COSV100172271; called by muse, mutect2
- ELAVL4 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63918218; called by muse, mutect2, varscan2
- ERC2 | c.2365C>T p.R789* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as rs752423372, COSV55625171; called by muse, mutect2, varscan2
- EXO1 | c.1228C>A p.L410I | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV62218486, COSV62220033; called by muse, mutect2, varscan2
- FCRLA | c.361C>T p.R121C (on ENST00000367959; = p.R98C on NM_032738.4) | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs147592382, COSV99376017; called by muse, mutect2, varscan2
- GALNT10 | c.828C>G p.Y276* | Nonsense Mutation (SNP) | VAF 118/193 reads (61%) | catalogued as rs770121388, COSV51732623, COSV51733628; called by muse, mutect2, varscan2
- GATA3 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 105/361 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1233918502, COSV60519439; called by muse, mutect2, varscan2
- GNPTG | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as rs367672512; called by muse, mutect2, varscan2
- GRIK1 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.456); catalogued as rs201996873, COSV58719356; called by muse, mutect2, varscan2
- GRIK5 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); catalogued as rs747382185; called by muse, mutect2, varscan2
- GRK2 | c.1908C>T p.S636= | Splice Region (SNP) | VAF 20/111 reads (18%) | catalogued as rs758888904; called by muse, mutect2, varscan2
- GUCY1B1 | c.1702A>G p.T568A | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.094); catalogued as rs369781139; called by muse, mutect2, varscan2
- HEATR1 | c.2386T>A p.F796I | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as rs746366377, COSV100857657; called by muse, mutect2, varscan2
- INHA | c.872G>T p.C291F | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54712616, COSV54730718, COSV99217542; called by muse, mutect2
- IRGC | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1283681745, COSV54984391, COSV54985786; called by muse, mutect2, varscan2
- KCNIP2 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as COSV99493184; called by muse, mutect2, varscan2
- KDR | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55766144; called by muse, mutect2, varscan2
- KLHL29 | c.2141C>G p.A714G | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV71992638; called by muse, mutect2, varscan2
- LIPK | c.588dup p.A197Cfs*9 | Frame Shift Ins (INS) | VAF 10/45 reads (22%) | catalogued as rs776732749; called by mutect2, pindel, varscan2
- LMTK2 | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs566255278; called by muse, mutect2, varscan2
- LRRC41 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs775910871, COSV58441063; called by muse, mutect2, varscan2
- MANEAL | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.039); catalogued as rs749699069; called by muse, mutect2, varscan2
- MARF1 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755521344, COSV60024036; called by muse, mutect2, varscan2
- MARS1 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777616090; called by muse, mutect2, varscan2
- MCCC1 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs777026304; called by muse, mutect2, varscan2
- MFAP2 | c.286+8C>T | Splice Region (SNP) | VAF 32/103 reads (31%) | catalogued as rs1199233359; called by muse, mutect2, varscan2
- MICB | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs775923426; called by muse, mutect2, varscan2
- MMP16 | c.1197C>A p.S399R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV54179992; called by muse, mutect2, varscan2
- MMS22L | c.2456G>A p.R819H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as rs1376328610; called by muse, mutect2, varscan2
- MSC | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs753728260, COSV100335782; called by muse, mutect2, varscan2
- MTUS2 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs558234447, COSV70919441; called by muse, mutect2, varscan2
- MX2 | c.992A>T p.Q331L | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100416211; called by muse, mutect2
- MXRA5 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 107/183 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs779077720, COSV99476977; called by muse, mutect2, varscan2
- MYO5A | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs569010771, COSV62562946; called by muse, mutect2, varscan2
- NCAM2 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 43/74 reads (58%) | catalogued as COSV53091176; called by muse, mutect2, varscan2
- NEB | c.15400C>T p.R5134* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as rs370098540; called by muse, mutect2, varscan2
- NPHS1 | c.2008G>A p.V670M | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs769106924; called by muse, mutect2, varscan2
- NUTM1 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs150270874; called by muse, mutect2, varscan2
- PAG1 | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55058105, COSV55058886; called by muse, mutect2, varscan2
- PCDHGA2 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.18); catalogued as COSV53955759; called by muse, mutect2, varscan2
- PCDHGA8 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 106/164 reads (65%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.041); catalogued as rs771645801, COSV53955769; called by muse, mutect2, varscan2
- PCLO | c.7597C>A p.P2533T | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.075); catalogued as COSV61637625; called by muse, mutect2, varscan2
- PGM2L1 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as rs779736186, COSV53347114; called by muse, mutect2, varscan2
- PIKFYVE | c.6199G>A p.V2067M | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100011509; called by muse, mutect2
- PKP2 | c.1063C>G p.R355G | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as CM1312958; called by muse, mutect2, varscan2
- POLR1G | c.1016T>C p.M339T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs778451525, COSV50004301; called by muse, mutect2, varscan2
- PPP1R12C | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as rs1348781448, COSV52380453; called by muse, mutect2, varscan2
- PTPRD | c.4186C>T p.R1396W | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61949608, COSV61983848; called by muse, mutect2, varscan2
- RADIL | c.3215C>T p.T1072M | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs762517849, COSV68200526; called by muse, mutect2, varscan2
- RBM10 | c.2522T>C p.I841T | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as rs142585482, COSV100238355; called by muse, mutect2
- RGS7 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV58536646, COSV58537594; called by muse, mutect2, varscan2
- SLC22A14 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as rs146612743; called by muse, mutect2, varscan2
- SMOX | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs375716040; called by muse, mutect2, varscan2
- SYNE1 | c.15815G>A p.R5272Q (on ENST00000367255 / NM_182961.4; = p.R5201Q on NM_033071.3) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs201750136; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBX2 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs373091690; called by muse, mutect2
- TRA2B | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs1188561599, COSV52025474; called by muse, mutect2, varscan2
- TRIM66 | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs974759812; called by muse, mutect2, varscan2
- TSPAN10 | c.457C>G p.P153A (on ENST00000574882 / NM_001290212.1; = p.P115A on NM_031945.4) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as rs753180923, COSV60773117; called by muse, mutect2
- USP2 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.813); catalogued as rs373153803; called by muse, varscan2
- USP28 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs554447859, COSV50168701; called by muse, mutect2, varscan2
- ZIC4 | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV67170786; called by muse, mutect2, varscan2
- ZNF526 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs773486582, COSV55899426; called by muse, mutect2, varscan2
- ZNF530 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 32/141 reads (23%) | catalogued as rs766100142; called by muse, mutect2, varscan2
- ZNF835 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1473583609, COSV73379763, COSV73379808; called by muse, mutect2, varscan2
- ZNF98 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.192); catalogued as COSV63336736; called by muse, mutect2, varscan2
- ADAMTS4 | c.2390G>C p.R797P | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | called by pindel, varscan2
- BPTF | c.3857T>G p.L1286R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNG1 | c.494T>C p.M165T | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CEP78 | c.1618G>T p.D540Y (on ENST00000424347 / NM_001349840.2; = p.D541Y on NM_032171.3) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CTNNA1 | c.1908G>T p.E636D | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, varscan2
- DDX25 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2
- DLG1 | c.1036A>G p.N346D | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- DNAAF1 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 53/197 reads (27%) | called by muse, mutect2, varscan2
- DOCK5 | c.1984G>C p.G662R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAT2 | c.4768G>T p.V1590F | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- FRY | c.7849C>A p.L2617I | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HHLA1 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- HNF1A | c.809A>C p.N270T | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- IFNA16 | c.65T>G p.L22R | Missense Mutation (SNP) | VAF 137/450 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- IGSF5 | c.309C>A p.N103K | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ITGA11 | c.1915G>A p.V639I | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- LARP1B | c.2594C>A p.S865Y | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MAU2 | c.1726C>T p.H576Y | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- MPDZ | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO18B | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- NELL2 | c.615G>T p.M205I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- NID1 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, varscan2
- OR52E4 | c.263G>A p.W88* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- PDGFRA | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- PIK3C2G | c.229T>G p.S77A | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PLCG1 | c.109_110del p.L37Vfs*37 | Frame Shift Del (DEL) | VAF 54/284 reads (19%) | called by mutect2, pindel, varscan2
- POU2F1 | c.1301A>G p.E434G (on ENST00000541643 / NM_001365848.1; = p.E457G on NM_002697.4) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRR33 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- PUF60 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- SF1 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- STXBP3 | c.1580dup p.N527Kfs*17 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- SYNE1 | c.14794G>A p.E4932K (on ENST00000367255 / NM_182961.4; = p.E4861K on NM_033071.3) | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THSD7B | c.3528C>A p.C1176* (on ENST00000272643; = p.C1174* on NM_001316349.2) | Nonsense Mutation (SNP) | VAF 69/142 reads (49%) | called by muse, mutect2, varscan2
- TRIM46 | c.28_30del p.F10del | In Frame Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, varscan2
- ZFHX4 | c.9536G>C p.G3179A | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZNF318 | c.2155G>T p.V719L | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACTL7B | c.198G>A p.A66= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs745654240, COSV65927430; called by muse, mutect2, varscan2
- ANK2 | c.5427G>A p.A1809= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs768956474; called by muse, mutect2, varscan2
- APOB | c.12429G>A p.E4143= | Silent (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- ATP2C2 | c.1818G>A p.T606= | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as rs777846440; called by muse, mutect2, varscan2
- CCKAR | c.780C>T p.S260= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as rs200117329; called by muse, mutect2, varscan2
- ENDOU | c.813T>C p.Y271= (on ENST00000422538 / NM_001172439.2; = p.Y230= on NM_006025.4) | Silent (SNP) | VAF 28/97 reads (29%) | called by muse, mutect2, varscan2
- ETV3L | c.411G>A p.P137= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs767316136, COSV71901025; called by muse, mutect2, varscan2
- FLNC | c.2595C>T p.H865= | Silent (SNP) | VAF 56/156 reads (36%) | catalogued as rs778744785; called by muse, mutect2, varscan2
- GBP6 | c.51C>T p.N17= | Silent (SNP) | VAF 41/166 reads (25%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.2136G>A p.S712= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs137922339; called by muse, mutect2, varscan2
- HEY2 | c.795C>T p.H265= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs1562713123, COSV64239579; called by muse, mutect2, varscan2
- IRX6 | c.927C>T p.C309= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs1308499227, COSV51860460; called by muse, mutect2, varscan2
- KY | c.1536C>T p.I512= | Silent (SNP) | VAF 34/107 reads (32%) | called by muse, mutect2, varscan2
- LAMB2 | c.2784C>T p.P928= | Silent (SNP) | VAF 48/177 reads (27%) | catalogued as COSV59733869; called by muse, mutect2, varscan2
- MARCHF11 | c.558C>T p.C186= | Silent (SNP) | VAF 57/163 reads (35%) | catalogued as rs1176344123; called by muse, mutect2, varscan2
- MGAM | c.3588G>A p.T1196= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs181422456, COSV101527356; called by muse, mutect2, varscan2
- MYH4 | c.1305C>T p.Y435= | Silent (SNP) | VAF 51/181 reads (28%) | catalogued as rs201920700, COSV55116378; called by muse, mutect2, varscan2
- N4BP1 | c.1719G>A p.S573= | Silent (SNP) | VAF 35/113 reads (31%) | catalogued as rs527362747, COSV52210201, COSV52210989; called by muse, mutect2, varscan2
- ONECUT3 | c.1284G>A p.T428= | Silent (SNP) | VAF 92/287 reads (32%) | called by muse, mutect2, varscan2
- OR10C1 | c.657C>T p.Y219= (on ENST00000622521; = p.Y217= on NM_013941.3) | Silent (SNP) | VAF 45/112 reads (40%) | called by muse, mutect2, varscan2
- PADI6 | c.372C>A p.V124= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs779935459, COSV100640031; called by muse, mutect2, varscan2
- PCDHGA6 | c.654C>T p.G218= | Silent (SNP) | VAF 65/123 reads (53%) | catalogued as rs1398535727, COSV53907857; called by muse, mutect2, varscan2
- PLCB2 | c.2559C>T p.S853= | Silent (SNP) | VAF 61/126 reads (48%) | catalogued as rs1283235504, COSV53033840; called by muse, mutect2, varscan2
- PLCE1 | c.4386C>T p.F1462= | Silent (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- PRDM10 | c.2799G>A p.A933= | Silent (SNP) | VAF 70/187 reads (37%) | catalogued as rs750585931, COSV58799123; called by muse, mutect2, varscan2
- PRDM14 | c.276G>T p.L92= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs766237068, COSV52574441; called by muse, mutect2, varscan2
- QRICH2 | c.4230C>T p.D1410= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as rs747795649, COSV53153978; called by muse, mutect2, varscan2
- RBM33 | c.969G>A p.P323= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs765658997, COSV56632826; called by muse, mutect2, varscan2
- RNF212 | c.90C>T p.C30= | Silent (SNP) | VAF 68/248 reads (27%) | catalogued as COSV61364095, COSV61364657; called by muse, mutect2, varscan2
- RSPH4A | c.1317A>G p.R439= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs774216430; called by muse, mutect2, varscan2
- RUBCN | c.2406G>A p.K802= | Silent (SNP) | VAF 51/166 reads (31%) | called by muse, mutect2, varscan2
- SCN10A | c.4767G>A p.A1589= | Silent (SNP) | VAF 82/228 reads (36%) | catalogued as rs768006927, COSV71862130; called by muse, mutect2, varscan2
- SEMA4F | c.867G>A p.T289= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as rs183059394, COSV60282457; called by muse, mutect2, varscan2
- SFRP1 | c.525C>T p.T175= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as rs761271626; called by muse, mutect2, varscan2
- SLC7A4 | c.321C>T p.Y107= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as rs373879064; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC8A2 | c.285G>A p.A95= | Silent (SNP) | VAF 90/285 reads (32%) | catalogued as rs1242842622; called by muse, mutect2, varscan2
- SPEG | c.8205G>T p.V2735= | Silent (SNP) | VAF 15/226 reads (7%) | catalogued as COSV100405751; called by muse, mutect2
- SRRM2 | c.2013T>C p.S671= | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as rs140110119; called by muse, mutect2, varscan2
- TAF4B | c.2355C>T p.D785= | Silent (SNP) | VAF 740/900 reads (82%) | catalogued as rs764132272; called by muse, varscan2
- VLDLR | c.1797C>A p.I599= | Silent (SNP) | VAF 29/86 reads (34%) | called by muse, mutect2, varscan2
- WDFY4 | c.6249C>T p.P2083= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- WDR49 | c.1515T>C p.G505= (on ENST00000308378 / NM_001366158.1; = p.G846= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 31/101 reads (31%) | called by mutect2, varscan2
- AC244258.1 | n.297C>A | RNA (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- BABAM2 | c.-9C>A | 5'UTR (SNP) | VAF 23/111 reads (21%) | catalogued as COSV100142165, COSV100142454; called by muse, mutect2, varscan2
- CBFA2T2 | c.719+534A>G | Intron (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- CLDN12 | c.*2115C>T | 3'UTR (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99842256; called by muse, mutect2, varscan2
- CLDN4 | c.*133C>A | 3'UTR (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99936620; called by muse, mutect2, varscan2
- DCK | c.*9A>T | 3'UTR (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- FAM50B | c.*6G>A | 3'UTR (SNP) | VAF 29/76 reads (38%) | catalogued as COSV100976623; called by muse, mutect2, varscan2
- IFNA14 | c.-14C>A | 5'UTR (SNP) | VAF 13/212 reads (6%) | catalogued as COSV101207355; called by muse, mutect2
- OR2H1 | c.*383G>T | 3'UTR (SNP) | VAF 8/44 reads (18%) | catalogued as COSV101009942; called by muse, varscan2
- SLC5A3 | c.*6624dup | 3'UTR (INS) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- SLITRK5 | c.*1056dup | 3'UTR (INS) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- SPATA13 | c.-222-26233C>T | Intron (SNP) | VAF 8/58 reads (14%) | catalogued as rs751685232; called by muse, mutect2, varscan2
- TCEA2 | c.517+18G>A | Intron (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- TMEM8B | c.-416C>T | 5'UTR (SNP) | VAF 23/78 reads (29%) | catalogued as rs551878462, COSV100941745; called by muse, mutect2, varscan2
